Somatic mutation profile of tumor specimen C3N-02973-01 (aliquot CPT0158800006) from CPTAC case C3N-02973, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 78.3 years (28,611 days).
Specimen C3N-02973-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c1d2200-0d2a-4190-9256-dc02f27e5d8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02973-31 (Blood Derived Normal), aliquot CPT0159500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d41e5dc1-5419-40d3-b7f7-da1caf6ab3a7

The open-access MAF lists 41 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Frame Shift Del 3, Nonsense Mutation 2, Intron 2, In Frame Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs199808841; called by muse, mutect2
- CAPZA2 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV63266368; called by muse, mutect2, varscan2
- CCDC88B | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 165/594 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100106055; called by muse, mutect2, varscan2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 53/282 reads (19%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- KDM5C | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62891312; called by muse, mutect2, varscan2
- KPNB1 | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV51594783; called by muse, mutect2, varscan2
- MYH1 | c.174del p.K59Rfs*2 | Frame Shift Del (DEL) | VAF 115/376 reads (31%) | catalogued as rs1177807589; called by mutect2, pindel, varscan2
- PRKCD | c.1798C>T p.H600Y | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100387960; called by muse, mutect2, varscan2
- SHANK1 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV53255058; called by muse, mutect2, varscan2
- SLX4 | c.5027C>T p.T1676I | Missense Mutation (SNP) | VAF 127/523 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs377544881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM1 | c.7883C>G p.A2628G | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV64430846; called by muse, mutect2, varscan2
- UGT8 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV60416449; called by muse, mutect2, varscan2
- USH2A | c.8506T>C p.Y2836H | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs760514091; called by muse, mutect2
- CCDC168 | c.14764A>G p.I4922V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.047); called by muse, mutect2
- CDKN2C | c.411_418del p.D138Lfs*2 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- CELSR2 | c.7776C>G p.Y2592* | Nonsense Mutation (SNP) | VAF 51/217 reads (24%) | called by muse, mutect2, varscan2
- CLCA4 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DSP | c.5011del p.E1671Nfs*10 | Frame Shift Del (DEL) | VAF 273/703 reads (39%) | called by mutect2, pindel, varscan2
- FSTL4 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FSTL5 | c.1148C>A p.P383Q | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MED12 | c.4043T>C p.L1348P | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPS35 | c.770C>G p.S257* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- NGB | c.435T>A p.S145R | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- NOVA2 | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); called by muse, mutect2
- RPS25 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SCGN | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- SEMA4A | c.1828C>T p.L610F | Missense Mutation (SNP) | VAF 106/455 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS1 | c.1809G>A p.V603= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as rs1362729548; called by muse, mutect2, varscan2
- ARFGEF2 | c.5118G>A p.R1706= | Silent (SNP) | VAF 72/260 reads (28%) | called by muse, mutect2, varscan2
- ATP11C | c.2730C>T p.Y910= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- BCAN | c.726G>A p.P242= | Silent (SNP) | VAF 80/299 reads (27%) | catalogued as rs137890862; called by muse, mutect2, varscan2
- COL8A1 | c.1980C>G p.V660= | Silent (SNP) | VAF 54/213 reads (25%) | called by muse, mutect2, varscan2
- MFHAS1 | c.591C>A p.P197= | Silent (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- MTR | c.963A>T p.G321= | Silent (SNP) | VAF 75/309 reads (24%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1068G>A p.S356= | Silent (SNP) | VAF 77/374 reads (21%) | called by muse, mutect2, varscan2
- PLD2 | c.2223C>T p.H741= | Silent (SNP) | VAF 54/296 reads (18%) | catalogued as rs755916788; called by muse, mutect2, varscan2
- SPATA31A3 | c.387A>G p.R129= | Silent (SNP) | VAF 106/504 reads (21%) | called by muse, mutect2
- AP000769.3 | chr11:65501251 del AT | 5'Flank (DEL) | VAF 11/39 reads (28%) | catalogued as rs751290649; called by pindel, varscan2
- FSTL3 | c.290-52_290-36del | Intron (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- KIR3DX1 | n.628G>A | RNA (SNP) | VAF 30/135 reads (22%) | catalogued as rs778842991; called by muse, mutect2, varscan2
- SYCE1 | c.196+19G>T | Intron (SNP) | VAF 37/176 reads (21%) | called by muse, mutect2, varscan2
